Somatic mutation profile of tumor specimen 0DM4XK from CCDI case PBBZYK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, benign; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.8 years (3,213 days).
Specimen 0DM4XK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84b6d31a-6f64-40b6-baa9-020a806d93e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM4X6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69616a33-0a6e-499e-8db2-db3ba0aba442

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, In Frame Ins 1, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 97/217 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.693); catalogued as COSV63309291, COSV63309392, COSV63309466; called by muse, mutect2, varscan2
- BRAF | c.1914_1915insGTT p.A638_T639insV (on ENST00000288602 / NM_001374244.1; = p.A598_T599insV on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Ins (INS) | VAF 104/468 reads (22%) | catalogued as COSV56086959, COSV56201191; called by mutect2, varscan2
- KIAA0825 | c.652A>G p.K218E | Missense Mutation (SNP) | VAF 137/438 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- DYNC2H1 | c.1185G>A p.A395= | Silent (SNP) | VAF 124/444 reads (28%) | catalogued as rs373327850; called by muse, mutect2, varscan2
- HMGB1 | c.*85T>C | 3'UTR (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100360835; called by mutect2, varscan2
